Somatic mutation profile of tumor specimen 0DDTEA from CCDI case PBBNZZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.9 years (6,185 days).
Specimen 0DDTEA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 100ae6bc-2a34-4155-b2f4-09861573f217.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDTEB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc811a9e-ad10-4fde-8e62-24eaa39bbb1a

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 4, Silent 3, 5'UTR 2, Nonsense Mutation 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L13 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 130/684 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58225044; called by mutect2, varscan2
- GPR37 | c.1444C>G p.R482G | Missense Mutation (SNP) | VAF 161/807 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58259947; called by muse, mutect2, varscan2
- HIVEP2 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 156/950 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs374725107; called by muse, mutect2, varscan2
- NUGGC | c.935G>T p.C312F | Missense Mutation (SNP) | VAF 107/380 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58432322; called by muse, mutect2, varscan2
- ADAR | c.2819T>A p.F940Y | Missense Mutation (SNP) | VAF 108/531 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARFGAP2 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 28/608 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CACNB4 | c.1253T>C p.L418S | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2
- CCDC7 | c.2537T>G p.I846S | Missense Mutation (SNP) | VAF 78/414 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, varscan2
- CTDNEP1 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 185/228 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRB | c.1345G>T p.G449W | Missense Mutation (SNP) | VAF 44/1064 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- IGSF9 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 145/677 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ITGA11 | c.3282A>T p.K1094N | Missense Mutation (SNP) | VAF 74/420 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LILRB5 | c.71-4C>A | Splice Region (SNP) | VAF 64/402 reads (16%) | called by muse, mutect2, varscan2
- MTHFD1L | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 66/416 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- SETD2 | c.6413A>G p.Q2138R | Missense Mutation (SNP) | VAF 162/425 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYT13 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- UAP1L1 | c.1088A>G p.Y363C | Missense Mutation (SNP) | VAF 23/846 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.045); called by muse, mutect2
- VPS13D | c.9421C>T p.R3141* | Nonsense Mutation (SNP) | VAF 22/436 reads (5%) | called by muse, mutect2
- BCO2 | c.453G>A p.P151= | Silent (SNP) | VAF 40/530 reads (8%) | catalogued as rs758755329, COSV63064989; called by muse, mutect2
- LAMC2 | c.121C>A p.R41= | Silent (SNP) | VAF 163/795 reads (21%) | catalogued as COSV99917364; called by mutect2, varscan2
- SH2D3A | c.1458C>T p.V486= | Silent (SNP) | VAF 106/584 reads (18%) | called by muse, varscan2
- CKS1B | c.-55G>A | 5'UTR (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2
- COL5A1 | c.5136+58T>G | Intron (SNP) | VAF 131/533 reads (25%) | catalogued as rs770417840; called by muse, mutect2, varscan2
- MYL3 | chr3:46830408 C>T | 3'Flank (SNP) | VAF 98/309 reads (32%) | catalogued as rs756554324, COSV101451263; called by muse, mutect2, varscan2
- RABL2B | c.137+18A>T | Intron (SNP) | VAF 53/667 reads (8%) | called by muse, mutect2
- SPAG5 | c.2797+11C>T | Intron (SNP) | VAF 167/1040 reads (16%) | called by muse, mutect2, varscan2
- SZT2 | c.4308+34A>C | Intron (SNP) | VAF 68/406 reads (17%) | called by muse, mutect2, varscan2
- WDR38 | c.-21G>T | 5'UTR (SNP) | VAF 60/316 reads (19%) | called by muse, mutect2, varscan2
